Surgical pathology report (de-identified scan), TCGA case TCGA-BG-A18B, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BG-A18B-01A (Primary Tumor).

PATIENT HISTORY:

CHIEF COMPLAINT/ PRE-OP/ POST-OP DIAGNOSIS: Endometrial cancer.

LMP DATE: Irregular bleeding.

PROCEDURE: Attempted robotic assist, bilateral salpingo-oophorectomy, total abdominal hysterectomy, bilateral pelvic lymph node dissection, removal of left thigh skin tag.

SPECIFIC CLINICAL QUESTION: Not provided.

OUTSIDE TISSUE DIAGNOSIS: No.

PRIOR MALIGNANCY: No.

CHEMORADIATION THERAPY: No.

OTHER DISEASES: No.

ICD-0-3
Adenocarcinoma, Endometrioid, NOS 8380/3
Site Code: Endometrium C54.1UUID: E7006FF4-33D9-4369-A4E0-42D124EAE1E0

**FINAL DIAGNOSIS:**

PART 1: UTERUS WITH BOTH ADNEXA, 220 GRAMS, TOTAL ABDOMINAL HYSTERECTOMY AND BILATERAL SALPINGO-OOPHORECTOMY -

- A. **ENDOMETRIOID ADENOCARCINOMA OF THE ENDOMETRIUM, WELL DIFFERENTIATED, INVOLVING 100% OF THE ENDOMETRIAL SURFACE UP TO THE LOWER UTERINE SEGMENT AND PENETRATES 10% OF THE MYOMETRIUM.**
- B. LYMPHOVASCULAR SPACE INVOLVEMENT NOT SEEN.
- C. CHRONIC CERVICITIS WITH SQUAMOUS METAPLASIA REACTIVE CHANGES.
- D. SUPERFICIAL ADENOMYOSIS.
- E. LEIOMYOMA.
- F. SEROSAL ADHESIONS.
- G. RIGHT AND LEFT FALLOPIAN TUBES WITH PARATUBAL CYST AND SEROSAL ADHESIONS.
- H. RIGHT AND LEFT OVARIES WITH PHYSIOLOGIC CHANGES.

PART 2: LEFT PELVIC LYMPH NODE, EXCISION -
TWO LYMPH NODES NEGATIVE FOR TUMOR.PART 3: RIGHT PELVIC LYMPH NODE, EXCISION -
THREE LYMPH NODES NEGATIVE FOR TUMOR.PART 4: SKIN LEFT THIGH, BIOPSY -
SKIN TAG.**COMMENT:**

Refer to

The lymph nodes show cluster of histiocytes and giant cells.

CASE SYNOPSIS:

SYNOPTIC - PRIMARY UTERINE ENDOMETRIAL CARCINOMA & CARCINOSARCOMA : HYSTERECTOMY SPECIMENS

TUMOR TYPE: Endometrioid adenocarcinoma, NOS
HISTOLOGIC GRADE (epithelial neoplasm) [combined architectural and nuclear]: Well differentiated (FIGO 1)

ARCHITECTURAL GRADE: Well differentiated

NUCLEAR GRADE: Grade 2

TUMOR SIZE: Maximum dimension: 60 mm

PERCENT OF ENDOMETRIAL SURFACE INVOLVEMENT:

DEPTH OF INVASION: Anterior endomyometrium: 100 %, Posterior endomyometrium: 100 %

ANGIOLYMPHATIC INVASION: Less than 1/2 thickness of myometrium

PRE-NEOPLASTIC CONDITIONS: No

OTHER: Complex endometrial hyperplasia with atypia

LYMPH NODES POSITIVE: Adenomyosis, Leiomyoma

LYMPH NODES EXAMINED: Number of lymph nodes positive: 0

T STAGE, PATHOLOGIC: Total number of lymph nodes examined: 5

N STAGE, PATHOLOGIC: pT1a

M STAGE, PATHOLOGIC: pN0

FIGO STAGE: Not applicable

IA

Source: NCI Genomic Data Commons file 82015e7d-cf3c-4c16-b5aa-bd9d1a8dde27 (TCGA-BG-A18B.E7006FF4-33D9-4369-A4E0-42D124EAE1E0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).